Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7213, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7213-01A (Primary Tumor).

[page 1 of 2]
Collection Date: [REDACTED]
Hospital of Origin: [REDACTED]
Copy to: [REDACTED]

TCGA-HC-7213

QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

A. Right and left pelvic lymph nodes; excision:

No metastatic carcinoma identified in four lymph nodes (0/4).

B. Prostate; radical prostatectomy:

Tumor Characteristics:

1. Histologic type: Prostatic adenocarcinoma.
2. Prostate size: 4.5 x 4.5 x 4.0 cm, 42.5 grams.
3. Tumor quantitation: Tumor involves approximately 25-30% of the prostate gland volume.
4. Gleason grade: ..
- a. Primary pattern: 4/5.
- b. Secondary pattern: 5/5.
- c. Total Gleason score: 9/10.
5. Extraprostatic extension: Focally present primarily associated with peripheral nerve in the soft tissue.
6. Seminal vesicle involvement: Bilateral.
7. Lymphovascular space invasion: Not identified..
8. High grade PIN: Present.
9. Treatment effect: Not identified.

Surgical Margin Status:

Surgical margins including apical (less than 0.1 cm), bladder neck, and inked prostatic margin negative for tumor.

Lymph Node Status:

1. Total number of lymph nodes received: Four, see specimen A.
2. Total number of lymph nodes containing metastatic carcinoma: Zero (0/4).

Other:

pTNM stage: pT3b N0.

COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Right and left pelvic lymph nodes

[page 2 of 2]
B. Prostate

PROCEDURAL DEMOGRAPHICS:

Date of Procedure

Accession Date/Time:

GROSS DESCRIPTION:

The specimen is received in two formalin filled containers labeled with the patient's name

A. Additionally labeled #1 and contains a 5.5 x 3.5 x 2.0 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, four firm fatty possible lymph nodes are identified ranging from 0.2 up to 3.0 cm in greatest dimension. They are entirely submitted in cassettes A1-4 labeled designated as follows: 1--two whole possible lymph nodes; 2--one whole possible bisected lymph node; 3-4--one whole possible bisected lymph node.

B. Additionally labeled #2 and contains a 42.5 gram, 4.5 x 4.5 x 4.0 cm prostate received with attached bilateral adnexa having overall dimensions of 5.0 x 3.0 x 2.0 cm. The capsule is pink-tan smooth to shaggy. The specimen is inked as follows: right side - blue; and left side - black. The base and apical margins are coned and serially sectioned. The remainder of the gland is serially sectioned from apex to base to reveal a pink-tan focally cystic cut surface with diffuse periurethral nodularity. A 3.5 x 3.0 x 2.5 cm yellow-tan nodular, glistening mass is present within the right base and partially surrounds the right seminal vesicle. This mass abuts the inked soft tissue margin. Representative sections are submitted in cassettes B1-22 labeled designated as follows: 1--right prostate/seminal vesicle junction; 2--left prostate/seminal vesicle junction; 3-4--apical margin, perpendicular; 5-6--base margin, perpendicular; 7-10--mass to inked soft tissue margin and right seminal vesicle; 11-13--right anterior prostate, apex to base; B14-16--right posterior prostate, apex to base; 17-19--left anterior prostate, apex to base; 20-22--left posterior prostate, apex to base.

Additionally, a yellow and green cassette are submitted for Genomics research each labeled

Source: NCI Genomic Data Commons file 0bcdcbec-3adf-453e-9d4e-27bce9a95c71 (TCGA-HC-7213.8B2F0B23-7A12-432A-B209-37E57A2F112B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).